TCGA case TCGA-41-2572 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e80ccf6-ef81-4662-bf5e-392f092c1e67

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 406 days (1.1 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 67.1 years (24,505 days); Year of diagnosis: 2009; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 34 days; Days to treatment end: 76 days; Treatment dose: 5,040 cGy; Chemo concurrent to radiation: Yes; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Temozolomide; Days to treatment start: 34 days; Days to treatment end: 76 days; Treatment dose: 7,740 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Cyberknife; Treatment intent type: Adjuvant; Days to treatment start: 78 days; Days to treatment end: 80 days; Treatment dose: 1,800 cGy; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 133 days; Days to treatment end: 351 days; Number of cycles: 13; Treatment dose: 15,600 mg; Prescribed dose: 1200; Prescribed dose units: mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 67.4 years (24,627 days); Days to diagnosis: 122 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 122 (post initial treatment): Progression or recurrence: Yes; Days to progression: 122 days.
- Days to follow up: 406 days (1.1 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-41-2572-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-41-2572-01A-01-BS1: Section location: Bottom; Percent tumor cells: 99; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0.
  Slide TCGA-41-2572-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-41-2572-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-41-2572-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent chemoradiation.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Radiation treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent Chemoradiation.
- Radiation treatment 2: Radiation type other: Cyber Knife.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 406 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 406 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 122 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-41-2572-01A-01D-1224-01): tumor purity 0.84, ploidy 1.96, whole-genome doublings 0.
